CCDI case PBBLZF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/7ae65992-6ac2-4af1-8625-e850f44d501d

Demographics
Sex at birth: female.

Diagnoses (1)
1. Tumor cells, malignant: ICD-O-3 morphology code: 8001/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 3.3 years (1,206 days).

Biospecimens (3 samples)
- Sample 0DC45X: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DC461: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DC463: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
